Somatic mutation profile of tumor specimen BA2311D (aliquot aq-BA2311D) from BEATAML1.0 case 2222, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myelomonocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 53.4 years (19,506 days).
Specimen BA2311D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8060114c-37bb-4ba7-ac2e-d3ff3984122a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2785D (Solid Tissue Normal), aliquot aq-BA2785D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/017e985d-cabd-43d3-90d4-3c7532f41a0a

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B3GAT1 | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.719); catalogued as rs749052528, COSV56995458; called by muse, mutect2, varscan2
- SLC27A1 | c.881C>A p.S294* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as rs1568417184, COSV99393503; called by muse, mutect2
- SNRPN | c.155A>G p.K52R | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.465); catalogued as rs771074349, COSV57593843, COSV57596019; called by muse, mutect2, varscan2
- GLP2R | c.1584C>A p.S528R | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2
- RHPN1 | c.1085C>A p.A362D | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); called by muse, mutect2
- TAB3 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.25); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- RASAL2 | c.54A>G p.S18= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as rs375225072; called by muse, mutect2, varscan2
- CSF1R | c.1754-28G>A | Intron (SNP) | VAF 40/78 reads (51%) | called by muse, varscan2
